Somatic mutation profile of tumor specimen 0DBPQV from CCDI case PBBLML, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (452 days).
Specimen 0DBPQV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e923567-ce8c-4ae2-b334-522cf7a537de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBPQW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18738f6c-19ce-4d80-8ad3-b508e1394c8c

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'Flank 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC16 | c.34382C>A p.T11461N | Missense Mutation (SNP) | VAF 96/474 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV67460006; called by muse, mutect2, varscan2
- CNOT1 | c.4800G>T p.K1600N | Missense Mutation (SNP) | VAF 47/419 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, varscan2
- GRB10 | c.32T>C p.L11S | Missense Mutation (SNP) | VAF 209/660 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZSCAN22 | c.559T>C p.S187P | Missense Mutation (SNP) | VAF 14/427 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- ABCB1 | c.3490-73C>A | Intron (SNP) | VAF 30/150 reads (20%) | called by muse, mutect2, varscan2
- CD84 | chr1:160548211 G>T | 3'Flank (SNP) | VAF 64/212 reads (30%) | catalogued as COSV100246300; called by muse, varscan2
- CRK | c.-81C>T | 5'UTR (SNP) | VAF 28/113 reads (25%) | catalogued as rs1253793204; called by muse, mutect2, varscan2
